Gene-level copy-number profile of tumor specimen TCGA-61-1724-01A from TCGA case TCGA-61-1724, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 47.0 years (17,168 days).
Specimen TCGA-61-1724-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.400e0133-bdd9-42b7-85cb-e486303ab5b2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-1724-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/32b0bf9a-6773-468f-9b69-0880d29ea951

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 1: 24,663; copy number 2: 27,207; copy number 3: 6,420; copy number 4: 857; copy number 5: 506; copy number 6: 111.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-61-1724-01): tumor purity 0.87, ploidy 1.76, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 43 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:205,913,048–206,062,257, 5 genes (within-gene range 0–1): SLC26A9, AL713965.1, RAB7B, CTSE, BX571818.1.
- chr10:126,905,409–127,452,517, 4 genes (within-gene range 0–1): DOCK1, AL359094.1, AL359094.2, INSYN2A.
- chr17:60,025,859–60,666,280, 28 genes: AC005702.3, HEATR6, MIR4737, AC005702.2, AC025048.4, WFDC21P, AC025048.6, AC025048.3, AC025048.2, AC025048.5, AC025048.7, AC025048.1, CA4, USP32, SCARNA20, AC104763.1, AC104763.2, H3P42, C17orf64, RPL12P38, APPBP2, AC011921.3, AC011921.1, AC011921.2, LINC01999, RPSAP66, PPM1D, RNU6-623P.
- chr17:60,696,313–60,900,185, 6 genes: RN7SL606P, AC110602.1, Y_RNA, KRT18P61, HMGN1P28, RN7SL448P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 617 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:37,350,934–41,242,154, 136 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr3:172,425,850–189,897,276, 312 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:195,553,792–198,222,513, 111 genes, copy number 6 (broad region; genes not listed).
- chr8:128,634,199–130,017,129, 18 genes, copy number 5 (within-gene range 3–5): CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, AC103718.1, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194.
- chr11:69,414,307–70,436,584, 33 genes, copy number 5: AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,477,592, 1 gene, copy number 5: AP001271.1.
- chr20:47,160,838–47,356,889, 6 genes, copy number 5: AL022342.1, MIR3616, ZMYND8, AL031666.2, AL031666.3, AL031666.1.

Autosomal genes at a single copy (total copy number 1): 24,223. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
